Somatic mutation profile of tumor specimen C3N-03186-01 (aliquot CPT0206880009) from CPTAC case C3N-03186, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.8 years (20,009 days).
Specimen C3N-03186-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c6ebbf9-6748-4047-9975-2a1e91143c0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03186-31 (Blood Derived Normal), aliquot CPT0206940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d2fde67-d2d5-4ca7-906e-129100364994

The open-access MAF lists 69 somatic variants for this specimen: 56 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 10, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, Splice Region 1, Splice Site 1, In Frame Ins 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 185/749 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs370266183, COSV100741592, COSV62789109; called by muse, mutect2, varscan2
- ACTL6A | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.851); catalogued as COSV66999428; called by muse, mutect2, varscan2
- ADAM7 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs760906182; called by muse, mutect2, varscan2
- ANO3 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs748171802, COSV56787167; called by muse, mutect2, varscan2
- ATP10B | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs754223933, COSV58777854; called by muse, mutect2, varscan2
- C3orf20 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 173/730 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs1041167391, COSV53784595, COSV99037587; called by muse, mutect2, varscan2
- COL3A1 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 119/602 reads (20%) | catalogued as COSV58593877; called by muse, mutect2, varscan2
- CSMD3 | c.5659G>A p.G1887R (on ENST00000297405 / NM_001363185.1; = p.G1783R on NM_052900.3) | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs149542393; called by muse, mutect2, varscan2
- DMKN | c.685T>C p.C229R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778044281; called by muse, mutect2, varscan2
- FRK | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs766270865, COSV101606663, COSV73384041; called by muse, mutect2, varscan2
- GABRR3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as rs564538143, COSV72084092; called by muse, mutect2, varscan2
- KRT27 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs115559932; called by muse, mutect2, varscan2
- LETM1 | c.2094_2096del p.E698del | In Frame Del (DEL) | VAF 69/361 reads (19%) | catalogued as rs1208396107; called by pindel, varscan2
- LILRB5 | c.1405G>A p.V469I (on ENST00000449561 / NM_001081442.3; = p.V468I on NM_006840.5) | Missense Mutation (SNP) | VAF 62/379 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs146369950; called by muse, mutect2, varscan2
- MBTPS2 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 13/370 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1216299718; called by muse, mutect2
- MGAT4C | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.69); catalogued as rs748796788, COSV59829726; called by muse, mutect2, varscan2
- OPRK1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs202165724, COSV55570192; called by muse, mutect2, varscan2
- OR1M1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 101/605 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs145395343; called by muse, mutect2, varscan2
- PCNT | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 139/664 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs201360311; called by muse, mutect2, varscan2
- PLCH2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as rs559294543; called by muse, mutect2, varscan2
- PRICKLE1 | c.1536T>G p.D512E | Missense Mutation (SNP) | VAF 122/506 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV58206954; called by muse, mutect2, varscan2
- PSG4 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 58/886 reads (7%) | catalogued as rs775914753; called by muse, mutect2
- SCAPER | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs369071392; called by muse, mutect2, varscan2
- THEGL | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960397172; called by muse, mutect2, varscan2
- TSPYL1 | c.725_726del p.V242Efs*52 | Frame Shift Del (DEL) | VAF 34/162 reads (21%) | catalogued as rs775957625; called by pindel, varscan2
- TTC26 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58272301; called by muse, varscan2
- XDH | c.1602C>T p.D534= | Splice Region (SNP) | VAF 124/563 reads (22%) | catalogued as rs61731080; called by muse, mutect2, varscan2
- APOOL | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- BRWD3 | c.2909T>G p.L970* | Nonsense Mutation (SNP) | VAF 52/249 reads (21%) | called by muse, mutect2, varscan2
- CENPI | c.1249T>A p.F417I | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- EHD3 | c.761T>A p.I254N | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FBN2 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 92/338 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FGD1 | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 89/417 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FGG | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 78/399 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- HMX1 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 131/476 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGA6 | c.3106-1G>C p.X1036_splice (on ENST00000442250; = p.X997_splice on NM_000210.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 81/598 reads (14%) | called by muse, mutect2, varscan2
- LRSAM1 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 102/458 reads (22%) | called by muse, mutect2, varscan2
- MAGED1 | c.1567A>G p.K523E | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- NPIPB2 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 75/676 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- PAPPA2 | c.3176C>G p.P1059R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHF1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 85/383 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- PHLPP2 | c.2100dup p.N701Qfs*42 | Frame Shift Ins (INS) | VAF 76/268 reads (28%) | called by mutect2, pindel, varscan2
- PIK3CA | c.1336_1338dup p.W446dup | In Frame Ins (INS) | VAF 287/772 reads (37%) | called by mutect2, pindel, varscan2
- PRKCQ | c.612del p.V205Lfs*2 | Frame Shift Del (DEL) | VAF 62/231 reads (27%) | called by mutect2, pindel, varscan2
- PRKRA | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 88/688 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRR16 | c.544G>T p.A182S (on ENST00000407149 / NM_001300783.2; = p.A159S on NM_016644.2) | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RHAG | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SPINT3 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 66/392 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM230 | c.347C>G p.P116R | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TMEM237 | c.693_697del p.F231Lfs*57 (on ENST00000409883 / NM_001044385.3; = p.F223Lfs*57 on NM_152388.4) | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- USP51 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSIG10L2 | c.1339G>C p.G447R | Missense Mutation (SNP) | VAF 88/395 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF714 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF729 | c.3422T>C p.F1141S | Missense Mutation (SNP) | VAF 72/365 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF8 | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAF | c.1500C>T p.Y500= | Silent (SNP) | VAF 53/330 reads (16%) | catalogued as rs755898303, COSV51694001; called by muse, mutect2, varscan2
- ARGFX | c.381G>A p.R127= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CD177 | c.270G>T p.R90= | Silent (SNP) | VAF 131/752 reads (17%) | catalogued as COSV65122746; called by muse, mutect2, varscan2
- GPNMB | c.462C>T p.N154= | Silent (SNP) | VAF 83/577 reads (14%) | catalogued as rs191779242; called by muse, mutect2, varscan2
- HMCN1 | c.3177C>T p.Y1059= | Silent (SNP) | VAF 89/353 reads (25%) | catalogued as rs757058220, COSV54881874; called by muse, mutect2, varscan2
- KIAA1210 | c.4458G>A p.S1486= | Silent (SNP) | VAF 54/206 reads (26%) | catalogued as rs771385213, COSV68175880; called by muse, mutect2
- OPN5 | c.579G>A p.S193= | Silent (SNP) | VAF 82/299 reads (27%) | catalogued as rs558057158, COSV55244308, COSV55247257; called by muse, mutect2, varscan2
- OTUD5 | c.141C>T p.G47= | Silent (SNP) | VAF 100/368 reads (27%) | catalogued as rs1334794433; called by muse, mutect2, varscan2
- PCDHA3 | c.1611G>A p.A537= | Silent (SNP) | VAF 309/1193 reads (26%) | catalogued as COSV63539318; called by muse, mutect2, varscan2
- TENM3 | c.7398G>A p.S2466= | Silent (SNP) | VAF 145/636 reads (23%) | catalogued as rs1485977049; called by muse, mutect2, varscan2
- CILP | c.-16C>T | 5'UTR (SNP) | VAF 38/192 reads (20%) | catalogued as rs774428788; called by muse, mutect2, varscan2
- IL31RA | c.1501+18G>A | Intron (SNP) | VAF 51/247 reads (21%) | catalogued as rs118134673, COSV51681274; called by muse, mutect2, varscan2
- THSD4 | c.1016-70098G>A | Intron (SNP) | VAF 125/584 reads (21%) | catalogued as rs765028905; called by muse, mutect2, varscan2
